Surgical pathology report (de-identified scan), TCGA case TCGA-4Z-AA7N, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-4Z-AA7N-01A (Primary Tumor).

[page 1 of 2]
Collect date:
(MM/DD/YYYY)

ICD-C-3
Carcinoma, urothelial NOS
8120/3
Date Bladder, lateral wall
C67.2
path Bladder, wall NOS
C67.9
JW 3/18/14

PATHOLOGY REPORT:

PRIMARY SITE: Bladder

Product of cystoprostatectomy:

High-grade urothelial carcinoma infiltrating the wall up to adipose tissue with surgical margins of the ureters and bladder wall free of neoplasia.

Presence of angiolymphatic and perineural infiltrations.

Prostate showing nodular hyperplasia, free of neoplasia.

Right and left seminal vesicles free of neoplasia.

Right and left vas deferens free of neoplasia.

Right side margin (separately):

Absence of neoplasia.

Right pelvic lymph nodes:

Absence of neoplasia: (0/13)

Left pelvic lymph nodes:

Absence of neoplasia: (0/10)

Per TSS, Stage is pT3.

[page 2 of 2]
TCGA Pathologic Diagnosis Discrepancy Form

V4.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name on OpenClinica): _____ Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	High grade urothelial carcinoma infiltrating the _____ wall up to adipose tissue.	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	High grade urothelial carcinoma of the bladder with invasion of the subserosal fat (pT3). This is an aggressive tumor with multiple lymph vascular emboli.	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	Case reviewed by _____ based on request from BCR.	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director	_____	Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file 55af58b0-8938-4aa7-850a-ab9c05dd2b4b (TCGA-4Z-AA7N.2CC89A9F-1F30-4232-B960-D8F54E7C57D4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).